Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4969, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4969-01A (Primary Tumor).

[page 1 of 2]
TCGA-BP-4969

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with enhancing right renal mass.

Specimens Submitted:

1: Kidney, Right, partial nephrectomy

DIAGNOSIS:

1. Kidney, Right, partial nephrectomy ():

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 1.9 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Cannot be assessed

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not Identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

Comment: Papillary adenoma (3.5 mm) present adjacent to carcinoma

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Gross Description:

1). The specimen is received fresh for intraoperative diagnosis labeled "Right partial nephrectomy". It consists of a 5.0 x 3.0 x 2.5 cm portion of kidney. There is perinephric fat attached to the specimen measuring 7 x 3.5 x 3 cm in greatest dimensions. The resected margin of the kidney is inked green. The outer surface of the fat is inked black. On cut section of the renal parenchyma, there is a 1.9 x 1.6 x 1.4 cm well circumscribed bright yellow-hemorrhagic tumor which is located 0.8 cm from the resected margin. The tumor impinges on the perinephric fat, but does not show any definite invasion. The remainder of the renal parenchyma shows brown tan unremarkable appearance. Representative sections are submitted. A sample of the tumor is given to TPS. There is no tissue frozen.

Summary of sections:

T -- tumor

M -- tumor and margin

FAT -tumor with fat

RS-representative sections of uninvolved renal parenchyma

FSC -- frozen section control

Summary of Sections:

Part 1: Kidney, Right, partial nephrectomy

Block	Sect. Site	PCs
1	FAT	1
1	FSC	1
2	M	2
1	RS	1

Intraoperative Consultation:

The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation

- 1) FROZEN SECTION DIAGNOSIS: TUMOR GROSSLY 1.0 CM FROM RESECTION MARGIN.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file d2b7262e-67ec-4b2c-b4ca-7191753f3a55 (TCGA-BP-4969.EEB068A7-649B-4EC3-A09D-60A98EFACF49.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).